Somatic mutation profile of tumor specimen 0DVHB2 from CCDI case PBCMLS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 6.5 years (2,356 days).
Specimen 0DVHB2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 055a3219-67e3-4feb-a444-9d977c3393cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVHAY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/216861a4-90dc-4dd9-b1ff-6a9436c6c697

The open-access MAF lists 36 somatic variants for this specimen: 18 protein-altering or splice-affecting, 12 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 12, Frame Shift Del 2, 5'Flank 2, Intron 2, Frame Shift Ins 1, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FSHR | c.1976C>T p.S659L | Missense Mutation (SNP) | VAF 270/610 reads (44%) | SIFT tolerated (0.65); PolyPhen benign (0.046); catalogued as COSV58622731; called by muse, varscan2
- OR5F1 | c.789T>A p.S263R | Missense Mutation (SNP) | VAF 55/750 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV53548919; called by muse, mutect2
- SYT14 | c.1011G>T p.M337I | Missense Mutation (SNP) | VAF 101/508 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as rs758291845, COSV55048846, COSV55054244; called by muse, varscan2
- TRIM60 | c.1370A>T p.D457V | Missense Mutation (SNP) | VAF 34/712 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1331686710; called by muse, mutect2
- UNC80 | c.4138C>T p.R1380C | Missense Mutation (SNP) | VAF 36/606 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55891195; called by muse, mutect2
- FCRL5 | c.921C>A p.H307Q | Missense Mutation (SNP) | VAF 155/655 reads (24%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.879); called by muse, varscan2
- GJA8 | c.953A>G p.E318G | Missense Mutation (SNP) | VAF 16/508 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- MRTFB | c.2768T>C p.I923T (on ENST00000571589 / NM_001365412.2; = p.I873T on NM_014048.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/345 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MYH11 | c.3988C>A p.Q1330K | Missense Mutation (SNP) | VAF 74/593 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- NRG3 | c.1257G>C p.L419F | Missense Mutation (SNP) | VAF 66/666 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.406); called by muse, mutect2
- PHOX2B | c.707_711del p.P236Qfs*122 | Frame Shift Del (DEL) | VAF 69/141 reads (49%) | called by mutect2, pindel, varscan2
- PLCE1 | c.4424_4463del p.I1475Tfs*23 | Frame Shift Del (DEL) | VAF 91/559 reads (16%) | called by mutect2, pindel, varscan2
- POM121L2 | c.2582G>C p.S861T | Missense Mutation (SNP) | VAF 29/480 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0.007); called by muse, mutect2
- PSG1 | c.1135C>G p.L379V | Missense Mutation (SNP) | VAF 28/760 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); called by muse, mutect2
- RPL10L | c.142C>A p.L48I | Missense Mutation (SNP) | VAF 100/332 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- RPL9 | c.249_252dup p.T85Cfs*30 | Frame Shift Ins (INS) | VAF 40/307 reads (13%) | called by mutect2, pindel, varscan2
- SLMAP | c.1261A>T p.S421C (on ENST00000428312 / NM_001377924.1; = p.S442C on NM_007159.5) | Missense Mutation (SNP) | VAF 40/510 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.736); called by muse, mutect2
- VSIG10L | c.2585C>T p.P862L | Missense Mutation (SNP) | VAF 36/205 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- B4GALNT4 | c.1539C>G p.P513= | Silent (SNP) | VAF 92/416 reads (22%) | called by muse, varscan2
- ETV6 | c.294C>T p.T98= | Silent (SNP) | VAF 30/1023 reads (3%) | called by muse, mutect2
- FBXL19 | c.1986C>T p.C662= | Silent (SNP) | VAF 44/760 reads (6%) | called by muse, mutect2
- FXR1 | c.12G>C p.L4= | Silent (SNP) | VAF 98/322 reads (30%) | catalogued as COSV99976004; called by muse, mutect2, varscan2
- GCM1 | c.783G>A p.K261= | Silent (SNP) | VAF 112/704 reads (16%) | called by muse, mutect2, varscan2
- MUC22 | c.2595C>A p.T865= | Silent (SNP) | VAF 46/899 reads (5%) | called by muse, mutect2
- MUC5AC | c.1941C>T p.A647= | Silent (SNP) | VAF 38/369 reads (10%) | catalogued as rs965276830; called by muse, mutect2
- PCDHGA12 | c.522G>A p.P174= | Silent (SNP) | VAF 16/354 reads (5%) | called by muse, mutect2
- PDZD7 | c.729T>C p.H243= | Silent (SNP) | VAF 32/541 reads (6%) | catalogued as rs369952350; called by muse, mutect2
- PRF1 | c.327C>G p.A109= | Silent (SNP) | VAF 177/684 reads (26%) | called by muse, mutect2, varscan2
- RNF103 | c.768G>A p.K256= | Silent (SNP) | VAF 50/582 reads (9%) | called by muse, mutect2
- SAMSN1 | c.219T>C p.S73= | Silent (SNP) | VAF 153/352 reads (43%) | called by muse, mutect2, varscan2
- ECSIT | c.945+15C>T | Intron (SNP) | VAF 215/537 reads (40%) | called by muse, mutect2, varscan2
- ECSIT | c.945+14G>A | Intron (SNP) | VAF 218/545 reads (40%) | called by muse, mutect2, varscan2
- EME1 | chr17:50373225 A>G | 5'Flank (SNP) | VAF 26/424 reads (6%) | called by muse, mutect2
- GGH | chr8:63038853 C>G | 5'Flank (SNP) | VAF 19/142 reads (13%) | called by muse, mutect2, varscan2
- KRTAP4-3 | c.*9G>T | 3'UTR (SNP) | VAF 25/807 reads (3%) | called by muse, mutect2
- MUC2 | chr11:1096141 C>G | 3'Flank (SNP) | VAF 38/318 reads (12%) | called by muse, varscan2
